Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3693, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3693-01A (Primary Tumor).

Diagnosis.

1. to 4.: Colon (sigmoid) resection material shows tumor-free oral and aboral resection margins and includes an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular fatty tissue, with two regional lymph node metastases and penetration of the peritoneum (1.) and with serosa (2.) and liver metastases (3. and 4.) (G2, pT4 L1 V0 pN1 2/17 pM1 HEP/PER).

Source: NCI Genomic Data Commons file ead3dff2-6ba1-4246-8c03-d7f57e97487a (TCGA-AA-3693.1D5ED0E0-FE91-4027-BA7A-A07E55C7796C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).